Somatic mutation profile of tumor specimen MBCProject_0343_T2_WES (aliquot MBCProject_0343_T2_WES_1) from CMI case MBCProject_0343, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Tissue or organ of origin: Breast, NOS.
Specimen MBCProject_0343_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 046f5651-6c81-4dd6-80cb-4852d4fbc523.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0343_SALIVA (Saliva), aliquot MBCProject_0343_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f5197b15-8756-4cb5-b5a7-a95caa9262e6

The open-access MAF lists 76 somatic variants for this specimen: 58 protein-altering or splice-affecting, 12 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 12, Frame Shift Del 4, Intron 3, Frame Shift Ins 2, Splice Site 1, 5'Flank 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ESR1 | c.1609T>A p.Y537N | Missense Mutation (SNP) | VAF 97/518 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52784978, COSV52804811, COSV99237981; called by muse, mutect2, varscan2
- APMAP | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.133); catalogued as rs1005872426; called by muse, mutect2, varscan2
- ATF5 | c.23G>A p.G8E | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.346); catalogued as rs1302076405; called by muse, mutect2, varscan2
- BEGAIN | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV62070301; called by muse, mutect2, varscan2
- CEL | c.17G>A p.R6H (on ENST00000673714; = p.R3H on NM_001807.6) | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as rs754771362; called by mutect2, varscan2
- CHPF | c.718G>A p.G240S | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.054); catalogued as rs1170614487, COSV99704654; called by muse, mutect2, varscan2
- CSN1S1 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 38/232 reads (16%) | SIFT tolerated (0.83); PolyPhen benign (0.046); catalogued as rs1266295913; called by muse, varscan2
- DHDH | c.710C>T p.T237M | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as rs762549322; called by muse, mutect2, varscan2
- DSCAML1 | c.4609C>T p.R1537W (on ENST00000321322; = p.R1477W on NM_020693.4) | Missense Mutation (SNP) | VAF 40/66 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs769974413; called by muse, mutect2, varscan2
- EFS | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 43/229 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs373577270; called by muse, mutect2, varscan2
- FBN3 | c.7849C>T p.R2617W | Missense Mutation (SNP) | VAF 88/142 reads (62%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.967); catalogued as rs201196689, COSV54461815; called by muse, mutect2, varscan2
- FBXL8 | c.366C>G p.D122E | Missense Mutation (SNP) | VAF 50/68 reads (74%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs970417954; called by muse, mutect2, varscan2
- FN1 | c.1423G>T p.G475W | Missense Mutation (SNP) | VAF 74/338 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100118036; called by muse, mutect2, varscan2
- KHNYN | c.756_759del p.Y253Lfs*49 | Frame Shift Del (DEL) | VAF 7/53 reads (13%) | catalogued as rs758799235; called by mutect2, pindel
- MXRA5 | c.4066C>A p.R1356S | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs1035250212, COSV54243360; called by muse, mutect2, varscan2
- PLXNA2 | c.4756C>T p.H1586Y | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65443461; called by muse, mutect2, varscan2
- RD3 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 45/359 reads (13%) | SIFT tolerated (0.97); PolyPhen benign (0.005); catalogued as COSV100879187, COSV65361821; called by muse, mutect2, varscan2
- SEMA3B | c.793G>A p.V265I | Missense Mutation (SNP) | VAF 76/143 reads (53%) | SIFT tolerated (0.62); PolyPhen benign (0.029); catalogued as rs781798375; called by muse, mutect2, varscan2
- TSKS | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs754948650; called by muse, mutect2, varscan2
- WFIKKN2 | c.280A>G p.M94V | Missense Mutation (SNP) | VAF 46/393 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs773394027; called by muse, mutect2, varscan2
- ANK2 | c.6088G>A p.E2030K | Missense Mutation (SNP) | VAF 68/160 reads (43%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.385); called by muse, varscan2
- ARHGAP25 | c.885C>G p.F295L (on ENST00000409202 / NM_001007231.3; = p.F287L on NM_014882.3) | Missense Mutation (SNP) | VAF 60/306 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- C19orf38 | c.169G>A p.V57M | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- CD1A | c.392T>C p.L131S | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- CFAP54 | c.8777C>T p.A2926V | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- CFAP77 | c.491T>C p.V164A | Missense Mutation (SNP) | VAF 83/441 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- COL25A1 | c.520T>A p.F174I | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CSMD3 | c.3019A>G p.T1007A (on ENST00000297405 / NM_001363185.1; = p.T903A on NM_052900.3) | Missense Mutation (SNP) | VAF 42/476 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.036); called by muse, mutect2
- CYP2S1 | c.759G>T p.Q253H | Missense Mutation (SNP) | VAF 43/186 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- DCTN3 | c.363G>C p.E121D | Missense Mutation (SNP) | VAF 41/231 reads (18%) | SIFT tolerated (0.73); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DGKQ | c.2382C>A p.H794Q | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- EBF1 | c.482G>A p.C161Y | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- GNL2 | c.636+1G>A p.X212_splice | Splice Site (SNP) | VAF 38/82 reads (46%) | called by muse, mutect2, varscan2
- GPR119 | c.344del p.K115Rfs*3 | Frame Shift Del (DEL) | VAF 66/242 reads (27%) | called by mutect2, pindel, varscan2
- HTR1B | c.190A>T p.T64S | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- KAT2B | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.023); called by muse, varscan2
- KIF2B | c.1130T>C p.L377P | Missense Mutation (SNP) | VAF 30/488 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- KRT6A | c.301G>T p.G101C | Missense Mutation (SNP) | VAF 46/649 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- MARCHF10 | c.868G>T p.D290Y | Missense Mutation (SNP) | VAF 28/456 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- MYH13 | c.279G>T p.M93I | Missense Mutation (SNP) | VAF 70/127 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- NBEA | c.8125A>G p.T2709A | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- NCOR1 | c.1699del p.A567Pfs*23 | Frame Shift Del (DEL) | VAF 138/281 reads (49%) | called by mutect2, pindel, varscan2
- NLRC3 | c.942C>G p.S314R | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OLFM4 | c.430A>G p.M144V | Missense Mutation (SNP) | VAF 78/176 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- OR4C5 | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 94/213 reads (44%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR9A2 | c.571A>T p.T191S | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- P2RX4 | c.1156C>G p.L386V | Missense Mutation (SNP) | VAF 78/133 reads (59%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- PSKH2 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 28/376 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2
- PTPRB | c.154T>C p.W52R | Missense Mutation (SNP) | VAF 36/920 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RNF213 | c.5674dup p.Y1892Lfs*40 | Frame Shift Ins (INS) | VAF 158/935 reads (17%) | called by mutect2, pindel, varscan2
- RYR3 | c.8878G>A p.A2960T (on ENST00000389232; = p.A2961T on NM_001036.6) | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SCYL2 | c.671C>T p.S224L | Missense Mutation (SNP) | VAF 69/184 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- SLFN14 | c.1470T>A p.H490Q | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.025); called by muse, mutect2
- TMBIM1 | c.426_439dup p.T147Mfs*8 | Frame Shift Ins (INS) | VAF 32/113 reads (28%) | called by mutect2, varscan2
- TMEM132C | c.502C>A p.P168T | Missense Mutation (SNP) | VAF 87/558 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TP53 | c.448_491del p.T150Afs*16 | Frame Shift Del (DEL) | VAF 96/184 reads (52%) | called by mutect2, pindel
- TPSD1 | c.53T>C p.V18A | Missense Mutation (SNP) | VAF 185/721 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TTF2 | c.1831C>G p.L611V | Missense Mutation (SNP) | VAF 57/154 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGAP25 | c.996C>T p.I332= (on ENST00000409202 / NM_001007231.3; = p.I324= on NM_014882.3) | Silent (SNP) | VAF 129/425 reads (30%) | called by muse, varscan2
- CARS2 | c.105C>T p.S35= | Silent (SNP) | VAF 97/158 reads (61%) | catalogued as rs1046292970; called by muse, mutect2, varscan2
- COL21A1 | c.2301G>A p.G767= | Silent (SNP) | VAF 27/89 reads (30%) | catalogued as rs777944369, COSV55169375; called by muse, mutect2, varscan2
- FADS2 | c.1200C>T p.A400= | Silent (SNP) | VAF 58/192 reads (30%) | called by muse, mutect2, varscan2
- FLNC | c.6441C>T p.I2147= | Silent (SNP) | VAF 106/521 reads (20%) | catalogued as rs762017885; ClinVar: likely benign / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- FOXF1 | c.717C>T p.H239= | Silent (SNP) | VAF 45/116 reads (39%) | catalogued as COSV99296296; called by muse, mutect2, varscan2
- NIPAL4 | c.1200C>T p.G400= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as rs759357633, COSV57424712; called by muse, varscan2
- NUDT10 | c.210G>T p.A70= | Silent (SNP) | VAF 81/183 reads (44%) | called by muse, mutect2, varscan2
- SERINC5 | c.253C>T p.L85= | Silent (SNP) | VAF 36/199 reads (18%) | called by muse, mutect2, varscan2
- SI | c.5118A>G p.K1706= | Silent (SNP) | VAF 42/276 reads (15%) | called by muse, mutect2, varscan2
- SRSF5 | c.336T>C p.V112= | Silent (SNP) | VAF 71/180 reads (39%) | called by muse, mutect2, varscan2
- ZFC3H1 | c.3672T>C p.S1224= | Silent (SNP) | VAF 14/300 reads (5%) | called by muse, mutect2
- AHCY | c.-36C>G | 5'UTR (SNP) | VAF 49/388 reads (13%) | catalogued as rs1488189759; called by muse, mutect2, varscan2
- AIMP1 | c.-26+189G>A | Intron (SNP) | VAF 55/130 reads (42%) | catalogued as rs546179277; called by muse, mutect2, varscan2
- CREB5 | chr7:28409892 C>A | 5'Flank (SNP) | VAF 62/381 reads (16%) | called by muse, mutect2, varscan2
- HOOK2 | c.1605+30C>A | Intron (SNP) | VAF 26/38 reads (68%) | called by muse, mutect2, varscan2
- PTH2 | c.*3G>A | 3'UTR (SNP) | VAF 52/212 reads (25%) | called by muse, mutect2, varscan2
- RIMS2 | c.2084-942G>C | Intron (SNP) | VAF 16/379 reads (4%) | catalogued as rs910081914; called by muse, mutect2
